CCDI case PBCBKH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/2a705551-4d70-49c2-ab0b-69a3da35ff5a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myxofibrosarcoma: ICD-O-3 morphology code: 8811/3; Tissue or organ of origin: Skin of lower limb and hip; Age at diagnosis: 15.0 years (5,492 days).

Biospecimens (4 samples)
- Sample 0DNYNP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNYO3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DPZTP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPZU8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
